Somatic mutation profile of tumor specimen TARGET-10-PAPHXJ-09A (aliquot TARGET-10-PAPHXJ-09A-01D) from TARGET case TARGET-10-PAPHXJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,768 days).
Specimen TARGET-10-PAPHXJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e84b7b4a-ad77-43f1-8894-611316f7e166.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHXJ-10A (Blood Derived Normal), aliquot TARGET-10-PAPHXJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06ecc773-4ad0-450c-a27e-6cbb59e84187

The open-access MAF lists 50 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Intron 6, Nonsense Mutation 3, 3'Flank 1, Splice Region 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.15688G>A p.E5230K | Missense Mutation (SNP) | VAF 130/179 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs867575884, COSV67994328; called by muse, mutect2, varscan2
- AKAP12 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.604); catalogued as rs914772647; called by muse, mutect2
- CLCNKA | c.1819C>A p.P607T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs772015448; called by mutect2, varscan2
- DOP1B | c.3331G>A p.E1111K | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756941986; called by muse, mutect2, varscan2
- ERBB4 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 92/173 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61468579; called by muse, mutect2, varscan2
- FSIP2 | c.17323C>T p.R5775* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as rs748336906, COSV100553556; called by muse, mutect2, varscan2
- KMT2C | c.9100C>T p.P3034S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs1016769957, COSV51389701; called by muse, mutect2, varscan2
- KRAS | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55561078, COSV55580549, COSV55715402; called by muse, mutect2, varscan2
- LRBA | c.6703C>T p.R2235W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763175357, COSV63958494; ClinVar: uncertain significance; called by mutect2, varscan2
- MEFV | c.2079G>A p.M693I | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV54825180; called by muse, mutect2, varscan2
- PARGP1 | n.1920C>T | Splice Region (SNP) | VAF 5/19 reads (26%) | catalogued as rs1274197519; called by muse, mutect2, varscan2
- RP9 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 65/157 reads (41%) | catalogued as rs1038654176, COSV51807788; called by muse, mutect2, varscan2
- SLC6A4 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as rs201425535; called by muse, mutect2, varscan2
- TENT5B | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100006480; called by muse, mutect2
- THSD4 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749505132; called by muse, mutect2, varscan2
- ADCY1 | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP77 | c.343C>G p.P115A | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAPLN1 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- HSPA8 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.484); called by muse, mutect2
- INTS6L | c.1742C>T p.T581I | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- KIAA1217 | c.4624G>A p.E1542K | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- KLHL15 | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.285); called by muse, mutect2
- MARCHF7 | c.1891C>A p.Q631K | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2
- MSMO1 | c.455_456insAGG p.W152delins* | Nonsense Mutation (INS) | VAF 49/112 reads (44%) | called by mutect2, pindel, varscan2
- PCNX4 | c.2149C>T p.L717F (on ENST00000406854 / NM_001330177.2; = p.L483F on NM_022495.5) | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB11A | c.185C>A p.A62E | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- RAP2C | c.81_90delinsCCCCT p.F28Pfs*2 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by pindel, varscan2*
- SRRM4 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIMM44 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- WDR6 | c.1424C>A p.A475D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.383); called by muse, varscan2
- WWC3 | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ZNF106 | c.3288G>T p.Q1096H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.132); called by mutect2, varscan2
- ZNF280C | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ZNF518A | c.4062C>A p.D1354E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARID1A | c.3675C>A p.S1225= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- CD209 | c.591C>T p.T197= | Silent (SNP) | VAF 61/221 reads (28%) | catalogued as rs994922101, COSV52649339, COSV52651003; called by muse, mutect2, varscan2
- EPB41L3 | c.1908C>T p.F636= | Silent (SNP) | VAF 52/90 reads (58%) | catalogued as COSV100550122; called by muse, mutect2, varscan2
- KRT40 | c.678C>T p.N226= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1255929462; called by muse, mutect2, varscan2
- LRBA | c.6096C>T p.I2032= | Silent (SNP) | VAF 38/63 reads (60%) | called by muse, varscan2
- MYOCD | c.1324C>T p.L442= | Silent (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- PCDHB1 | c.2427C>A p.G809= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100128248; called by muse, mutect2
- PCNX4 | c.2148C>T p.S716= (on ENST00000406854 / NM_001330177.2; = p.S482= on NM_022495.5) | Silent (SNP) | VAF 61/115 reads (53%) | catalogued as rs778202805; called by muse, mutect2, varscan2
- IGKV1D-13 | chr2:90154574 ins C | 3'Flank (INS) | VAF 47/52 reads (90%) | called by mutect2, varscan2*
- IQSEC2 | c.2460-38G>A | Intron (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- NDRG1 | c.100-47G>T | Intron (SNP) | VAF 4/35 reads (11%) | called by mutect2, varscan2
- NEU3 | c.94+895C>A | Intron (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- NPAS2 | c.-23+646C>T | Intron (SNP) | VAF 18/40 reads (45%) | catalogued as rs1445339271; called by muse, mutect2, varscan2
- PATZ1 | c.1335+1270G>T | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- RANBP17 | c.1710+60543G>T | Intron (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- TMEM132E | chr17:34579231 C>T | 5'Flank (SNP) | VAF 20/33 reads (61%) | called by muse, mutect2, varscan2
